Somatic mutation profile of tumor specimen TCGA-05-4420-01A (aliquot TCGA-05-4420-01A-01D-1265-08) from TCGA case TCGA-05-4420, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 41.5 years (15,159 days).
Specimen TCGA-05-4420-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16aa8b2b-9ec5-4a55-8c41-45245a48e055.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4420-10A (Blood Derived Normal), aliquot TCGA-05-4420-10A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d39851c-b7e3-4b8e-a3ea-da1a307eb6fe

The open-access MAF lists 310 somatic variants for this specimen: 227 protein-altering or splice-affecting, 71 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 189, Silent 71, Nonsense Mutation 19, Frame Shift Del 8, Splice Site 7, RNA 5, Intron 3, 3'UTR 3, Splice Region 2, Nonstop Mutation 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 72/181 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>T p.R280I | Missense Mutation (SNP) | VAF 20/53 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1165C>A p.Q389K | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV55294071; called by muse, mutect2, varscan2
- ADAM19 | c.1852G>T p.G618C | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57433555; called by muse, mutect2, varscan2
- ADAMTS16 | c.2010C>A p.Y670* | Nonsense Mutation (SNP) | VAF 29/85 reads (34%) | catalogued as COSV56996354; called by muse, mutect2, varscan2
- ADAMTS20 | c.1973G>T p.C658F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67131103, COSV67134545; called by muse, mutect2, varscan2
- ADGRB3 | c.2290G>T p.A764S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.546); catalogued as rs112866971, COSV65404904; called by muse, mutect2
- ADGRG4 | c.4688C>A p.S1563Y | Missense Mutation (SNP) | VAF 96/132 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as COSV54960926; called by muse, varscan2
- AL358113.1 | c.3874G>T p.E1292* | Nonsense Mutation (SNP) | VAF 23/101 reads (23%) | catalogued as COSV61958267; called by muse, mutect2, varscan2
- ALKBH1 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV53174524; called by muse, mutect2, varscan2
- AOC3 | c.1108G>T p.A370S | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0.023); catalogued as COSV53827684, COSV53828686; called by muse, mutect2, varscan2
- APCDD1 | c.121A>C p.K41Q | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV62372754; called by muse, mutect2
- ARAP1 | c.2452T>A p.F818I (on ENST00000393609 / NM_001040118.2; = p.F573I on NM_015242.4) | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV61992268; called by muse, mutect2, varscan2
- ARFIP1 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as COSV61884145, COSV61885304; called by muse, mutect2, varscan2
- ARHGEF12 | c.4405C>A p.P1469T | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.283); catalogued as COSV63105914; called by muse, mutect2, varscan2
- ASTN1 | c.2020G>T p.D674Y | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV56067894, COSV56075142; called by muse, mutect2, varscan2
- C6orf15 | c.904C>A p.R302S | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.275); catalogued as COSV52538944; called by muse, mutect2
- CACNA1A | c.2327C>A p.S776Y | Missense Mutation (SNP) | VAF 102/168 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV64203139; called by muse, mutect2, varscan2
- CACNA1C | c.259G>T p.G87W | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV59733195, COSV59740528; called by muse, varscan2
- CACNA1E | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as COSV100704646; called by muse, mutect2, varscan2
- CALY | c.360+2T>C p.X120_splice | Splice Site (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99428625; called by muse, mutect2
- CASP2 | c.96G>T p.M32I | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60082726; called by muse, mutect2, varscan2
- CCDC54 | c.792T>G p.S264R | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as COSV53759113; called by muse, mutect2, varscan2
- CD2AP | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV63761553, COSV63762531; called by muse, mutect2, varscan2
- CD36 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.771); catalogued as COSV59210658; called by muse, varscan2
- CDH2 | c.1269T>G p.S423R | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.368); catalogued as COSV52286206; called by muse, mutect2, varscan2
- CDK5RAP3 | c.436A>T p.K146* | Nonsense Mutation (SNP) | VAF 57/137 reads (42%) | catalogued as COSV58115455; called by muse, mutect2, varscan2
- CDK7 | c.83A>G p.K28R | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV99841678; called by muse, mutect2
- CDKN1B | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 79/214 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV57431620, COSV99963911; called by muse, mutect2, varscan2
- CFAP251 | c.833G>T p.C278F | Missense Mutation (SNP) | VAF 83/188 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV56612377; called by muse, mutect2, varscan2
- CHD7 | c.7309G>T p.G2437* | Nonsense Mutation (SNP) | VAF 47/80 reads (59%) | catalogued as COSV101418178; called by muse, mutect2, varscan2
- CHD7 | c.7310G>T p.G2437V | Missense Mutation (SNP) | VAF 46/77 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV101418179; called by muse, mutect2, varscan2
- CHRM3 | c.1683C>A p.C561* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as COSV55094228; called by muse, mutect2, varscan2
- CLCN1 | c.1867G>T p.G623W | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58371742; called by muse, varscan2
- CLCN1 | c.1918G>T p.V640F | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58371752; called by muse, varscan2
- CLDN18 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV104415890, COSV59302618; called by muse, mutect2, varscan2
- CLSTN2 | c.2867A>G p.*956Wext*14 | Nonstop Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as COSV71722301; called by muse, mutect2, varscan2
- CMTR2 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 64/98 reads (65%) | catalogued as COSV57603841; called by muse, mutect2, varscan2
- CNGA2 | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 73/98 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as rs752041390, COSV61705255, COSV61706611; called by muse, mutect2, varscan2
- COL5A2 | c.3118A>T p.N1040Y | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV66411351; called by muse, mutect2, varscan2
- COL5A3 | c.1926G>T p.Q642H | Missense Mutation (SNP) | VAF 138/185 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53414021; called by muse, mutect2, varscan2
- CORO7 | c.2388G>T p.E796D | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52031789; called by muse, mutect2, varscan2
- CRYBA4 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 54/350 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV61322374; called by muse, varscan2
- CTTN | c.513G>T p.K171N | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57233801; called by muse, mutect2, varscan2
- CYP2A13 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773217452, COSV57838738; called by muse, mutect2, varscan2
- CYP2B6 | c.338T>A p.V113E | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV57844657; called by muse, mutect2, varscan2
- CYP4B1 | c.1081G>T p.G361C | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99597062; called by muse, mutect2, varscan2
- DAB1 | c.934C>G p.L312V (on ENST00000371231; = p.L279V on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.313); catalogued as COSV64694609; called by muse, mutect2, varscan2
- DACH1 | c.1330A>T p.S444C (on ENST00000619232 / NM_001366712.1; = p.S392C on NM_080759.6) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV100498128, COSV100499508; called by muse, mutect2, varscan2
- DCHS2 | n.5991C>T | Splice Region (SNP) | VAF 7/29 reads (24%) | catalogued as COSV61775043; called by muse, mutect2, varscan2
- DENND2A | c.1246C>A p.Q416K | Missense Mutation (SNP) | VAF 106/246 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0.165); catalogued as COSV52054193; called by muse, mutect2, varscan2
- DGKI | c.1522C>A p.P508T | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV55959874; called by muse, mutect2, varscan2
- DNAH11 | c.8543A>T p.Q2848L | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV60965289; called by muse, mutect2, varscan2
- DNAH7 | c.2059-2A>T p.X687_splice | Splice Site (SNP) | VAF 24/49 reads (49%) | catalogued as COSV56773115; called by muse, mutect2, varscan2
- DNAH8 | c.12664T>C p.Y4222H | Missense Mutation (SNP) | VAF 79/269 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.052); catalogued as COSV59461162; called by muse, mutect2, varscan2
- DSCAM | c.2330G>A p.S777N | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs756353534, COSV68030619; called by muse, mutect2, varscan2
- DST | c.21883C>G p.R7295G (on ENST00000361203 / NM_001374722.1; = p.R4968G on NM_015548.5) | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV55024640; called by muse, mutect2, varscan2
- DST | c.1223G>A p.G408E (on ENST00000361203 / NM_001374722.1; = p.G82E on NM_001723.6) | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV55000055, COSV99753308; called by muse, mutect2, varscan2
- DVL2 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50037306; called by muse, mutect2, varscan2
- EDEM2 | c.1702G>T p.A568S | Missense Mutation (SNP) | VAF 146/375 reads (39%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); catalogued as COSV63259618; called by muse, mutect2, varscan2
- EDEM2 | c.1000A>T p.R334W | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65713247; called by muse, mutect2, varscan2
- EPHA6 | c.1760C>A p.T587K | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV67580201; called by muse, mutect2, varscan2
- EPHB6 | c.2897A>T p.Y966F | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63892479; called by muse, mutect2, varscan2
- ERVW-1 | c.907C>A p.Q303K | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.351); catalogued as rs755860362, COSV101423829; called by muse, mutect2, varscan2
- FAM131B | c.241C>G p.R81G | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV68126437; called by muse, varscan2
- FAM47B | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 45/59 reads (76%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV61455355; called by muse, mutect2, varscan2
- FBXO33 | c.1025A>T p.H342L | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99980852; called by muse, mutect2, varscan2
- FLI1 | c.1301C>G p.P434R | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV55646039; called by muse, mutect2, varscan2
- FLNC | c.1228G>T p.V410F | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV57958991; called by muse, mutect2, varscan2
- FMR1NB | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT tolerated (0.47); PolyPhen benign (0.047); catalogued as COSV65072373; called by muse, mutect2, varscan2
- FRMPD3 | c.4735G>C p.D1579H | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1399042173, COSV99346144; called by muse, mutect2, varscan2
- GALNT15 | c.1310G>A p.R437K | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60218257; called by muse, mutect2, varscan2
- GATA3 | c.1326G>T p.M442I | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV60520327; called by muse, mutect2, varscan2
- GBP5 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58592732, COSV58593360; called by muse, mutect2, varscan2
- GLI3 | c.2182C>G p.L728V | Missense Mutation (SNP) | VAF 24/295 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756678135, COSV67885544, COSV67890924; called by muse, mutect2
- GMPS | c.1605A>T p.K535N | Missense Mutation (SNP) | VAF 83/223 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV55810455; called by muse, mutect2, varscan2
- GPRIN3 | c.2201C>A p.S734Y | Missense Mutation (SNP) | VAF 52/256 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561174618, COSV60885465; called by muse, mutect2, varscan2
- GRAMD1C | c.107A>G p.E36G | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV63983225; called by muse, mutect2, varscan2
- HAUS6 | c.689A>T p.K230I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100787212; called by mutect2, varscan2
- HELB | c.583A>C p.M195L | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV56074613; called by muse, mutect2, varscan2
- HELZ2 | c.6809G>A p.R2270Q (on ENST00000467148 / NM_001037335.2; = p.R1701Q on NM_033405.3) | Missense Mutation (SNP) | VAF 107/332 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs143065747; called by muse, mutect2, varscan2
- HGF | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV55952487; called by muse, mutect2, varscan2
- HOXC9 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV100327440; called by muse, mutect2, varscan2
- HP1BP3 | c.1489A>T p.K497* | Nonsense Mutation (SNP) | VAF 21/119 reads (18%) | catalogued as COSV56563425; called by muse, mutect2, varscan2
- IFNA16 | c.495G>T p.E165D | Missense Mutation (SNP) | VAF 102/267 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101207066; called by muse, mutect2, varscan2
- IFNG | c.385C>A p.Q129K | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57491572; called by muse, mutect2, varscan2
- IGSF9B | c.3754A>G p.T1252A | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as COSV58069792; called by mutect2, varscan2
- IL4R | c.238G>T p.G80* | Nonsense Mutation (SNP) | VAF 81/160 reads (51%) | catalogued as COSV50152115, COSV99405502; called by muse, mutect2
- KDM2A | c.3284C>G p.S1095C | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV58190531; called by muse, mutect2, varscan2
- KDM5A | c.31G>C p.A11P | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.146); catalogued as rs1223268592, COSV66994073; called by muse, mutect2, varscan2
- KDM5C | c.1518G>T p.M506I | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64766487; called by muse, mutect2, varscan2
- KIF1A | c.2344C>A p.R782S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV57494105, COSV57504132; called by muse, mutect2
- KIF9 | c.917-1G>C p.X306_splice | Splice Site (SNP) | VAF 30/122 reads (25%) | catalogued as COSV55521061; called by muse, mutect2, varscan2
- KLRC2 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as rs143264024; called by muse, mutect2, varscan2
- LAMA1 | c.6787G>T p.V2263L | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV67539731; called by muse, mutect2, varscan2
- LAMP3 | c.839A>T p.N280I | Missense Mutation (SNP) | VAF 175/439 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV55615637; called by muse, mutect2, varscan2
- LAMP5 | c.816C>A p.D272E | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55716985; called by muse, mutect2, varscan2
- LAT | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV62795947; called by muse, mutect2, varscan2
- LGR5 | c.1022C>A p.S341* | Nonsense Mutation (SNP) | VAF 32/105 reads (30%) | catalogued as COSV57005296; called by muse, mutect2, varscan2
- LLGL1 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57499100; called by muse, mutect2, varscan2
- LRP2 | c.3302G>T p.C1101F | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55561118; called by muse, mutect2, varscan2
- LY75 | c.4835G>T p.S1612I | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as COSV55108680; called by muse, mutect2, varscan2
- MAP2 | c.4522G>T p.A1508S | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as COSV52297811; called by muse, mutect2, varscan2
- MCM2 | c.2048A>G p.H683R | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54034963; called by muse, mutect2, varscan2
- MDGA2 | c.1952T>A p.L651* (on ENST00000399232 / NM_001113498.2; = p.L353* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as COSV62101372; called by muse, mutect2, varscan2
- MEIS1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV55489201; called by muse, mutect2, varscan2
- MIGA1 | c.1768C>A p.Q590K | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV66224097; called by muse, mutect2, varscan2
- MMP9 | c.791C>A p.T264N | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV63434228; called by muse, mutect2, varscan2
- MMUT | c.1574G>T p.R525M | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV51276021; called by muse, mutect2
- MROH7 | c.568G>T p.G190C | Missense Mutation (SNP) | VAF 82/129 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV59874518; called by muse, mutect2, varscan2
- MS4A12 | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.758); catalogued as COSV50014179; called by muse, mutect2, varscan2
- MTM1 | c.307G>T p.G103* | Nonsense Mutation (SNP) | VAF 12/17 reads (71%) | catalogued as COSV60336158; called by muse, mutect2, varscan2
- MUC16 | c.20218G>T p.G6740C | Missense Mutation (SNP) | VAF 308/404 reads (76%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV67477684; called by muse, mutect2, varscan2
- MUC16 | c.13996C>A p.L4666I | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as COSV67477690; called by muse, mutect2
- MUC5AC | c.14083T>A p.C4695S | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0); catalogued as COSV100611410; called by muse, mutect2, varscan2
- NANS | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV52964457; called by muse, mutect2, varscan2
- NCKAP5 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 34/78 reads (44%) | catalogued as COSV58456625; called by muse, mutect2, varscan2
- NCOA1 | c.909G>T p.Q303H | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV56048020; called by muse, mutect2, varscan2
- NECAB1 | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV70241532; called by muse, mutect2, varscan2
- NEU4 | c.989C>A p.P330H (on ENST00000391969 / NM_001167602.3; = p.P342H on NM_080741.4) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as COSV57991199; called by muse, mutect2, varscan2
- NGF | c.111G>T p.W37C | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.408); catalogued as COSV101049446; called by muse, mutect2, varscan2
- NLRP6 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as COSV56460686; called by muse, mutect2, varscan2
- NOTCH4 | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); catalogued as COSV66682019; called by muse, mutect2, varscan2
- NPTX2 | c.823C>A p.Q275K | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1172767592, COSV55717923; called by muse, mutect2, varscan2
- OAS3 | c.626G>T p.W209L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57447143; called by muse, mutect2, varscan2
- OGA | c.1121A>G p.Y374C | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778330794, COSV63382285; called by muse, mutect2, varscan2
- OR10A2 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.174); catalogued as COSV100225018; called by muse, mutect2, varscan2
- OR10J3 | c.470C>A p.A157D | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100171709; called by muse, mutect2, varscan2
- OR10Q1 | c.163A>C p.T55P | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as COSV57471062; called by muse, mutect2, varscan2
- OR10S1 | c.836G>T p.S279I | Missense Mutation (SNP) | VAF 33/307 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV73342887; called by muse, mutect2, varscan2
- OR1L3 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.141); catalogued as COSV59170138; called by muse, mutect2, varscan2
- OR2C3 | c.679T>A p.L227M | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as COSV63575528; called by muse, mutect2, varscan2
- OR2J2 | c.766G>T p.V256F | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV65848171; called by muse, mutect2, varscan2
- OR4C12 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.672); catalogued as rs141386333, COSV58859946, COSV58861260; called by muse, mutect2, varscan2
- OR4C15 | c.90G>C p.K30N | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.283); catalogued as COSV58953930; called by muse, mutect2, varscan2
- OR5D14 | c.626A>T p.E209V | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV59457209; called by muse, mutect2, varscan2
- OR5T1 | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 81/266 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV100478914; called by muse, mutect2, varscan2
- OR6S1 | c.452G>T p.W151L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57838622; called by muse, mutect2, varscan2
- OR8U1 | c.169A>C p.T57P | Missense Mutation (SNP) | VAF 60/227 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100163869; called by muse, mutect2, varscan2
- OTOGL | c.3568G>T p.E1190* (on ENST00000547103; = p.E1181* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as COSV101509168, COSV72007126; called by muse, mutect2, varscan2
- OTOS | c.70G>T p.V24L | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56228494; called by muse, mutect2, varscan2
- PCDH18 | c.2210G>T p.R737M | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs1202495172, COSV61269854; called by muse, mutect2, varscan2
- PCDH9 | c.526G>T p.V176L | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as COSV60566380; called by muse, mutect2, varscan2
- PCOLCE2 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs547465850, COSV56000275; called by muse, mutect2, varscan2
- PDZD2 | c.1665G>A p.Q555= | Splice Region (SNP) | VAF 57/124 reads (46%) | catalogued as COSV56863754; called by muse, mutect2, varscan2
- PFDN5 | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 119/320 reads (37%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as rs146649111; called by muse, mutect2, varscan2
- PGM5 | c.572-1G>A p.X191_splice | Splice Site (SNP) | VAF 22/167 reads (13%) | catalogued as COSV67164381; called by muse, mutect2, varscan2
- PIK3C3 | c.151C>G p.Q51E | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV56281442; called by muse, mutect2, varscan2
- PIP5K1C | c.1683G>T p.R561S | Missense Mutation (SNP) | VAF 40/53 reads (75%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.02); catalogued as COSV58953887; called by muse, mutect2
- PLA1A | c.1043A>T p.K348M | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV56332571; called by muse, mutect2, varscan2
- POLB | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55345407, COSV99612810; called by muse, mutect2, varscan2
- POSTN | c.2465A>T p.K822I | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.229); catalogued as COSV65713600; called by muse, mutect2, varscan2
- POTEE | c.2831A>T p.D944V | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV58235766; called by muse, varscan2
- PPP1R3D | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.939); catalogued as rs780653470, COSV100674497; called by muse, mutect2, varscan2
- PRAMEF12 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as rs761506783, COSV63215894; called by muse, mutect2
- PRAMEF4 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 72/416 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs781218379, COSV52439599; called by muse, mutect2, varscan2
- PSPC1 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.604); catalogued as COSV58889116; called by muse, mutect2, varscan2
- PTCHD4 | c.770G>C p.C257S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as COSV59789908; called by muse, mutect2, varscan2
- PTPRU | c.1146G>T p.E382D | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.708); catalogued as COSV60531261; called by muse, mutect2, varscan2
- RAB8B | c.145A>C p.T49P | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100368881; called by muse, mutect2, varscan2
- RGS12 | c.3752G>T p.R1251L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV58754231; called by muse, varscan2
- RGS3 | c.952C>G p.P318A (on ENST00000350696 / NM_001282923.2; = p.P206A on NM_017790.4) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58282652; called by muse, mutect2, varscan2
- RPL21 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV55388159, COSV55388813; called by muse, mutect2, varscan2
- RPS29 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV99817905; called by muse, mutect2, varscan2
- RRAGD | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV63269590; called by muse, mutect2, varscan2
- S1PR3 | c.229T>C p.F77L | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.138); catalogued as COSV63980854; called by muse, mutect2, varscan2
- SATB2 | c.1067C>A p.S356Y | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV53487984, COSV53488243; called by muse, mutect2, varscan2
- SCRG1 | c.239C>A p.P80Q | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56635809; called by muse, mutect2, varscan2
- SEMA6B | c.943G>T p.G315W | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56704788; called by muse, mutect2, varscan2
- SERPINB7 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1230400829, COSV60534722; called by muse, mutect2, varscan2
- SH3BGRL2 | c.182A>C p.Q61P | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.825); catalogued as COSV63964820; called by muse, mutect2, varscan2
- SH3RF1 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52922481; called by muse, mutect2, varscan2
- SKP2 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.69); catalogued as COSV56951134; called by muse, mutect2, varscan2
- SLC17A3 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.905); catalogued as COSV100399174; called by muse, mutect2, varscan2
- SLC25A11 | c.318T>A p.F106L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV52591443; called by muse, mutect2, varscan2
- SLC2A3 | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 75/276 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.06); catalogued as COSV50004659; called by muse, mutect2, varscan2
- SLC35D2 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53563565; called by muse, mutect2, varscan2
- SLC9B1 | c.322G>T p.G108W | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56472279; called by muse, mutect2, varscan2
- SLITRK2 | c.567G>C p.R189S | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59426895; called by muse, mutect2, varscan2
- SLITRK2 | c.2423G>T p.R808M | Missense Mutation (SNP) | VAF 62/91 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as COSV59426901; called by muse, mutect2, varscan2
- SP140L | c.1237G>T p.G413W | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54745701; called by muse, mutect2, varscan2
- SPAG16 | c.671A>T p.E224V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55987541; called by muse, mutect2, varscan2
- SPAG17 | c.5747T>G p.L1916W | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV60462448; called by muse, mutect2, varscan2
- SPAG17 | c.2483G>A p.R828K | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV104413214, COSV60462454; called by muse, mutect2, varscan2
- SRCAP | c.1553G>T p.S518I | Missense Mutation (SNP) | VAF 86/154 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV52675935; called by muse, mutect2, varscan2
- STEAP2 | c.623T>A p.L208H | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99840358; called by muse, mutect2, varscan2
- SUGT1 | c.673C>T p.L225F (on ENST00000343788 / NM_001130912.3; = p.L193F on NM_006704.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV59421030; called by muse, mutect2, varscan2
- SVEP1 | c.1653T>A p.N551K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV57040945; called by muse, mutect2, varscan2
- TCAF1 | c.371T>C p.V124A | Missense Mutation (SNP) | VAF 71/220 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.467); catalogued as COSV63518393; called by muse, mutect2, varscan2
- THNSL1 | c.1795C>T p.H599Y | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as COSV64479547; called by muse, mutect2
- THNSL2 | c.1213G>T p.D405Y | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV59083700; called by muse, mutect2, varscan2
- TMEM200A | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as COSV51652458, COSV51655562; called by muse, mutect2, varscan2
- TMEM39B | c.894C>A p.Y298* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | catalogued as COSV100297993; called by muse, mutect2, varscan2
- TMTC1 | c.2057T>G p.L686W (on ENST00000539277 / NM_001193451.2; = p.L578W on NM_175861.3) | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV55486555; called by muse, mutect2, varscan2
- TPO | c.1918G>C p.A640P | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV61105177; called by muse, mutect2, varscan2
- TRAT1 | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV55469483; called by muse, mutect2, varscan2
- TRHDE | c.2996C>G p.T999S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV53852526, COSV53870923; called by muse, varscan2
- UBE2O | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 63/344 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60064958; called by muse, mutect2, varscan2
- UBN2 | c.1550A>G p.K517R | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs1162855483, COSV56032802; called by muse, mutect2, varscan2
- UMODL1 | c.566C>G p.P189R | Missense Mutation (SNP) | VAF 49/257 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV68556832; called by muse, mutect2, varscan2
- USF2 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV99723388; called by muse, mutect2, varscan2
- USP19 | c.1984-1G>T p.X662_splice | Splice Site (SNP) | VAF 23/107 reads (21%) | catalogued as COSV100026077; called by muse, mutect2, varscan2
- USP42 | c.844C>G p.Q282E | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV60361885; called by muse, mutect2, varscan2
- USP6 | c.763A>C p.K255Q | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.291); catalogued as COSV51487603; called by muse, mutect2, varscan2
- USP8 | c.971A>G p.Q324R | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1307099388, COSV56165783; called by muse, mutect2, varscan2
- WDHD1 | c.77+1G>T p.X26_splice | Splice Site (SNP) | VAF 33/180 reads (18%) | catalogued as COSV100216381, COSV59461077; called by muse, mutect2, varscan2
- WWC2 | c.1438G>T p.V480L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100968271; called by muse, mutect2
- XIRP2 | c.9253G>T p.E3085* (on ENST00000628543; = p.E3260* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | catalogued as COSV54713569; called by muse, mutect2, varscan2
- ZIC4 | c.811T>A p.C271S | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67172725; called by muse, mutect2, varscan2
- ZNF236 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 50/133 reads (38%) | catalogued as rs376042351; called by muse, mutect2, varscan2
- ZNF239 | c.989A>G p.Q330R | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as rs1418180610, COSV100021777; called by muse, mutect2, varscan2
- ZNF550 | c.1093C>T p.H365Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57306095; called by muse, mutect2
- ZNF592 | c.3086G>T p.R1029L | Missense Mutation (SNP) | VAF 118/392 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV55438007, COSV55438632; called by muse, mutect2, varscan2
- ZNF614 | c.1312A>G p.T438A | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.371); catalogued as COSV54547102; called by muse, mutect2, varscan2
- ZNF660 | c.795G>C p.Q265H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV59549517; called by muse, mutect2, varscan2
- ZNF665 | c.439G>T p.G147C (on ENST00000600412; = p.G212C on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs779971809, COSV67216142; called by muse, mutect2, varscan2
- CEP68 | c.1237_1243del p.R413Sfs*4 | Frame Shift Del (DEL) | VAF 24/217 reads (11%) | called by mutect2, pindel
- COQ10B | c.502_523del p.S168Qfs*31 | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | called by mutect2, pindel
- FLG | c.12076_12101del p.R4026Gfs*9 | Frame Shift Del (DEL) | VAF 26/111 reads (23%) | called by mutect2, pindel, varscan2
- LAMA1 | c.6970del p.A2324Lfs*3 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel
- LPIN1 | c.657_658del p.A220Cfs*11 | Frame Shift Del (DEL) | VAF 59/237 reads (25%) | called by mutect2, pindel*, varscan2*
- MIER1 | c.996del p.K332Nfs*25 (on ENST00000355356 / NM_001077701.3; = p.K349Nfs*25 on NM_020948.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 21/141 reads (15%) | called by mutect2, pindel, varscan2
- PXDNL | c.3403del p.V1135Wfs*28 | Frame Shift Del (DEL) | VAF 20/190 reads (11%) | called by mutect2, pindel*
- SCAF4 | c.1727_1728+25del p.X576_splice | Splice Site (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- TRAV18 | c.295C>A p.Q99K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.114); called by mutect2, varscan2
- UBE2D3 | c.234dup p.N79* | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | called by mutect2, pindel
- ZFHX4 | c.10675_10676del p.C3559Qfs*17 | Frame Shift Del (DEL) | VAF 15/139 reads (11%) | called by pindel, varscan2
- AC109583.1 | c.435C>T p.S145= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100167858; called by muse, mutect2, varscan2
- ALDH1A3 | c.1341T>C p.N447= | Silent (SNP) | VAF 57/166 reads (34%) | catalogued as COSV60902398; called by muse, mutect2, varscan2
- ANKRD42 | c.819T>C p.P273= | Silent (SNP) | VAF 48/118 reads (41%) | catalogued as COSV52616870; called by muse, mutect2, varscan2
- AP3B2 | c.432C>A p.P144= | Silent (SNP) | VAF 23/170 reads (14%) | catalogued as COSV55611310; called by muse, mutect2, varscan2
- C18orf25 | c.247C>A p.R83= | Silent (SNP) | VAF 56/160 reads (35%) | catalogued as COSV56367380; called by muse, mutect2, varscan2
- C6orf136 | c.402C>G p.S134= | Silent (SNP) | VAF 81/197 reads (41%) | catalogued as COSV53314909; called by muse, mutect2, varscan2
- CCT8L2 | c.786T>C p.S262= | Silent (SNP) | VAF 10/204 reads (5%) | catalogued as COSV63463025; called by muse, mutect2
- CDH7 | c.924C>A p.G308= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV59888952; called by muse, mutect2, varscan2
- CMYA5 | c.4893G>T p.P1631= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV71407262; called by muse, mutect2, varscan2
- CSMD2 | c.10362G>T p.R3454= | Silent (SNP) | VAF 103/665 reads (15%) | catalogued as COSV53929831; called by muse, mutect2, varscan2
- CSN1S1 | c.270G>A p.S90= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs1315496477, COSV55889654, COSV55890366; called by muse, mutect2, varscan2
- CYP4B1 | c.1080G>T p.L360= | Silent (SNP) | VAF 36/245 reads (15%) | catalogued as COSV99597060; called by muse, mutect2, varscan2
- CYP4F8 | c.39G>T p.P13= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV100358026, COSV57854536; called by muse, mutect2
- DHX57 | c.3207C>A p.G1069= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as COSV54887483; called by muse, mutect2, varscan2
- DUSP15 | c.696G>A p.Q232= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV54067099; called by muse, mutect2, varscan2
- EPHA2 | c.906G>A p.E302= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100626070, COSV64453844; called by muse, mutect2, varscan2
- FAM131B | c.732C>T p.Y244= | Silent (SNP) | VAF 38/260 reads (15%) | catalogued as rs201753321, COSV58371758; called by muse, mutect2, varscan2
- FAM135B | c.462C>A p.V154= | Silent (SNP) | VAF 38/320 reads (12%) | catalogued as COSV50530229, COSV50535320; called by muse, varscan2
- FAM83F | c.1302C>A p.P434= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV61000602; called by muse, mutect2, varscan2
- GABRA3 | c.540C>A p.L180= | Silent (SNP) | VAF 61/89 reads (69%) | catalogued as COSV100942496, COSV100942612; called by muse, mutect2, varscan2
- GOLIM4 | c.402C>T p.D134= | Silent (SNP) | VAF 34/200 reads (17%) | catalogued as COSV58330584; called by muse, mutect2, varscan2
- HDAC7 | c.1260G>C p.V420= (on ENST00000427332; = p.V459= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/194 reads (19%) | catalogued as rs770321899, COSV50386036; called by muse, mutect2, varscan2
- HES4 | c.138C>G p.R46= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100515151; called by muse, mutect2, varscan2
- IKZF1 | c.186G>A p.Q62= | Silent (SNP) | VAF 43/254 reads (17%) | catalogued as COSV58788465; called by muse, mutect2, varscan2
- KCNA10 | c.705G>A p.L235= | Silent (SNP) | VAF 55/144 reads (38%) | catalogued as COSV63904555; called by muse, mutect2, varscan2
- KCNH8 | c.2736C>T p.S912= | Silent (SNP) | VAF 43/85 reads (51%) | catalogued as COSV60469107; called by muse, mutect2, varscan2
- KIR3DL2 | c.1149G>T p.V383= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as COSV54393633; called by muse, varscan2
- LMNB2 | c.666G>A p.R222= | Silent (SNP) | VAF 20/143 reads (14%) | catalogued as rs376727524; called by muse, mutect2, varscan2
- MMUT | c.435C>T p.G145= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs1284213862, COSV51276084; called by muse, mutect2, varscan2
- NLGN4Y | c.831C>T p.I277= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV100196682; called by muse, mutect2, varscan2
- NPAT | c.2229C>T p.I743= | Silent (SNP) | VAF 45/131 reads (34%) | catalogued as rs745435232, COSV53719232; called by muse, mutect2, varscan2
- NTN1 | c.1290G>T p.T430= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs1014499318, COSV51484496, COSV51488955; called by muse, mutect2, varscan2
- OR10J3 | c.471C>A p.A157= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as COSV100171707; called by muse, mutect2, varscan2
- OR2Z1 | c.184C>T p.L62= | Silent (SNP) | VAF 188/231 reads (81%) | catalogued as COSV60692833; called by muse, mutect2, varscan2
- OR51E2 | c.699G>T p.R233= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV67807897; called by muse, varscan2
- OR7A10 | c.127C>T p.L43= | Silent (SNP) | VAF 35/60 reads (58%) | catalogued as COSV50166498; called by muse, mutect2, varscan2
- PARVB | c.927G>A p.P309= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs764558419, COSV58688624; called by muse, mutect2, varscan2
- PCDHGB5 | c.2157C>T p.A719= | Silent (SNP) | VAF 159/266 reads (60%) | catalogued as COSV53980284; called by muse, mutect2, varscan2
- PDILT | c.120G>T p.L40= | Silent (SNP) | VAF 80/152 reads (53%) | catalogued as COSV56703040; called by muse, mutect2, varscan2
- PEX14 | c.1095G>A p.R365= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV63062108; called by muse, mutect2, varscan2
- PXDN | c.3204G>T p.A1068= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV53239460; called by muse, mutect2
- RBP3 | c.937C>T p.L313= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs1565764655; called by muse, mutect2, varscan2
- RLF | c.207A>T p.S69= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as COSV65652328; called by muse, mutect2, varscan2
- RNF152 | c.237C>T p.I79= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs750723774, COSV100455120; called by muse, mutect2, varscan2
- RNH1 | c.130C>A p.R44= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV62251349; called by muse, mutect2, varscan2
- SCUBE3 | c.1473A>G p.K491= | Silent (SNP) | VAF 47/302 reads (16%) | catalogued as COSV51458404; called by muse, mutect2, varscan2
- SDK1 | c.6228C>T p.T2076= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as rs141297041; called by muse, mutect2, varscan2
- SEMA6D | c.2742G>A p.S914= (on ENST00000316364 / NM_153618.2; = p.S852= on NM_020858.2) | Silent (SNP) | VAF 38/195 reads (19%) | catalogued as rs765465054, COSV60373313; called by muse, mutect2, varscan2
- SETBP1 | c.4014C>A p.P1338= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV56328284; called by muse, mutect2, varscan2
- SLC14A1 | c.870C>T p.S290= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as COSV58933056; called by muse, mutect2, varscan2
- SLC17A4 | c.1005C>T p.A335= | Silent (SNP) | VAF 112/293 reads (38%) | catalogued as rs1260033467, COSV64956606; called by muse, mutect2, varscan2
- SLC38A7 | c.345C>T p.Y115= | Silent (SNP) | VAF 37/70 reads (53%) | catalogued as COSV54703592; called by muse, mutect2, varscan2
- SLC39A12 | c.699T>C p.F233= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as COSV66200155; called by muse, mutect2, varscan2
- SLC7A10 | c.693G>T p.V231= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV53505365; called by muse, mutect2, varscan2
- SLC7A4 | c.1479C>G p.G493= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV60384773; called by muse, mutect2, varscan2
- SLC8A1 | c.1278C>A p.A426= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV60487254; called by muse, mutect2, varscan2
- SPIDR | c.756A>T p.S252= | Silent (SNP) | VAF 45/295 reads (15%) | catalogued as COSV52379618; called by muse, mutect2, varscan2
- SPTA1 | c.5709A>T p.I1903= | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as COSV63756162; called by muse, mutect2, varscan2
- SUPV3L1 | c.750A>T p.P250= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV62845768; called by muse, mutect2
- TENM2 | c.1866C>T p.C622= (on ENST00000518659 / NM_001122679.2; = p.C390= on NM_001080428.3) | Silent (SNP) | VAF 14/224 reads (6%) | catalogued as rs1250665629, COSV69135071; called by muse, mutect2
- THOP1 | c.459G>T p.G153= | Silent (SNP) | VAF 37/55 reads (67%) | catalogued as COSV57019421; called by muse, mutect2, varscan2
- TMEM132D | c.393C>A p.A131= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV70612299; called by muse, mutect2, varscan2
- TMEM201 | c.553C>T p.L185= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV100440377; called by muse, mutect2, varscan2
- TNNI3 | c.321G>T p.V107= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV61277962; called by muse, mutect2, varscan2
- TRPV5 | c.294G>T p.L98= | Silent (SNP) | VAF 56/136 reads (41%) | catalogued as COSV54687511; called by muse, mutect2, varscan2
- TTLL3 | c.573A>T p.S191= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV59614973; called by muse, mutect2, varscan2
- UBE2D1 | c.243T>C p.N81= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV100877761; called by muse, mutect2, varscan2
- WDR72 | c.162G>A p.A54= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as rs545775155, COSV64747210; called by muse, mutect2, varscan2
- XDH | c.2343G>A p.L781= | Silent (SNP) | VAF 30/259 reads (12%) | catalogued as COSV65149834; called by muse, mutect2, varscan2
- ZFP36L1 | c.282G>A p.G94= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as COSV60546230; called by muse, mutect2, varscan2
- ZNF609 | c.1488C>T p.D496= | Silent (SNP) | VAF 60/140 reads (43%) | catalogued as COSV58586288; called by muse, mutect2, varscan2
- AC073310.1 | n.127C>T | RNA (SNP) | VAF 12/89 reads (13%) | catalogued as rs529814469; called by muse, mutect2, varscan2
- AC244258.1 | n.894C>A | RNA (SNP) | VAF 28/128 reads (22%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846680 G>T | 5'Flank (SNP) | VAF 28/39 reads (72%) | called by muse, mutect2, varscan2
- ANKRD13D | c.*401G>C | 3'UTR (SNP) | VAF 20/120 reads (17%) | catalogued as COSV100398435; called by muse, mutect2, varscan2
- C1QTNF3 | c.84+68G>T | Intron (SNP) | VAF 203/369 reads (55%) | catalogued as rs745884570, COSV99180702; called by muse, mutect2, varscan2
- DCHS2 | n.3986C>A | RNA (SNP) | VAF 4/16 reads (25%) | catalogued as COSV61775049; called by muse, mutect2, varscan2
- DCHS2 | n.3985C>A | RNA (SNP) | VAF 4/16 reads (25%) | catalogued as rs769362367, COSV100601603; called by muse, mutect2, varscan2
- MACF1 | c.15832-9693C>G | Intron (SNP) | VAF 43/81 reads (53%) | catalogued as COSV57119645, COSV57130122; called by muse, mutect2, varscan2
- SERPINA13P | n.814G>A | RNA (SNP) | VAF 36/158 reads (23%) | catalogued as rs765939949; called by muse, mutect2, varscan2
- TNKS1BP1 | c.*2A>T | 3'UTR (SNP) | VAF 37/115 reads (32%) | catalogued as COSV100835967; called by muse, mutect2, varscan2
- TRAK1 | c.*2G>T | 3'UTR (SNP) | VAF 29/71 reads (41%) | catalogued as COSV100565497; called by muse, mutect2, varscan2
- TTN | c.10360+1631G>T | Intron (SNP) | VAF 22/112 reads (20%) | catalogued as COSV60172177; called by muse, mutect2, varscan2
